Somatic mutation profile of tumor specimen TARGET-10-PARTJJ-09A (aliquot TARGET-10-PARTJJ-09A-01D) from TARGET case TARGET-10-PARTJJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,170 days).
Specimen TARGET-10-PARTJJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5ba2bf0-cebd-4bf4-97bc-914677289892.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTJJ-10A (Blood Derived Normal), aliquot TARGET-10-PARTJJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8ed79a0-f0b2-4c6e-952c-853f0f18972a

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPNT | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as rs745380935; called by muse, mutect2, varscan2
- CSRP1 | c.271A>G p.K91E | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- TUBA3E | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- CALCOCO1 | c.1898+68C>A | Intron (SNP) | VAF 21/87 reads (24%) | catalogued as COSV100017183; called by muse, mutect2, varscan2
- DIP2C | c.85+38428G>A | Intron (SNP) | VAF 35/140 reads (25%) | called by muse, mutect2, varscan2
- LINC02054 | n.2375C>T | RNA (SNP) | VAF 35/85 reads (41%) | catalogued as rs1447205118; called by muse, mutect2, varscan2
